Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6817, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6817-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No. 3

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total organ resection – stomach**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **suspected gastric cancer**

Examination performed on:

Macroscopic description:

The collected material consisting of the stomach, after being incised along the greater curvature, sized 18 x 19.5 cm with the omentum sized 35 x 16 x 4.5 cm, without macroscopic focal lesions.

Ulcerations sized 2.5 x 2.6 x 1.5 cm found in the mucous membrane. Distance from the proximal end 11 cm, from distal end, 6.5 cm.

Microscopic description:

Adenocarcinom tubulare partim male differentiatum G3.

Tumour penetrating the full thickness of the stomach wall and perigastric fat tissue.

Surgical incision lines free of neoplastic invasion.

Omentum sine metastasibus.

Invasio carcinomatosa vasorum.

Mucosa outside the tumour showing features of chronic infection.

Final diagnoses to be given after final analysis of the material.

Compliance validated by:

Examination performed on:

Lymph nodes:

- periorificial: metastases carcinomatosae in lymponodis No III/IX

Infiltratio carcinomatosa capsulae lymphonodorum.

- lesser curvature: metastases carcinomatosae in lymphonodis NO VIII/X.

Infiltratio carcinomatosa capsulae lymphonodorum.

- greater curvature: metastases carcinomatosae in lymphonodis NO VIII/X.

- peripyloric: metastases carcinomatosae in lymphonodo NO I/III.

And as per preliminary diagnosis

[page 2 of 2]
Examination No.: [REDACTED]

Patient: XXX

PESEL: XXX

Gender: [REDACTED]

Examination performed on: [REDACTED]

Histopathological Diagnosis:

Adenocarcinoma tubulare partim male differentiatum ventriculi. Tubular and in part poorly differentiated adenocarcinoma of the stomach.

Metastases carcinomatosae in lymphonodis. Cancer metastases in the lymph nodes. NO XX/XXXI.

Typus intestinalis sec [REDACTED] Intestinal type acc. to [REDACTED]

G3, pT2b, pN3.

Compliance validated by: [REDACTED]

CONTACT YOU DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 3ff0e4bb-599c-4c41-a298-728042621453 (TCGA-D7-6817.D7FFF3CA-F8B2-4CE6-9896-F37C022CFC60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).